Surgical pathology report (de-identified scan), TCGA case TCGA-08-0353, project TCGA-GBM (Glioblastoma Multiforme), tissue source site UCSF, specimen TCGA-08-0353-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

FINAL PATHOLOGIC DIAGNOSIS

- A. Brain, left anterior temporal, biopsy of mass: WHO glioblastoma multiforme, grade IV; see comment.
- B. Brain, left anterior temporal, tumor resection: WHO glioblastoma multiforme, grade IV; see comment.
- C. Brain, left anterior temporal, tumor aspiration: Grey and white matter with scattered foci of infiltrating neoplastic astrocytes.

COMMENT: The heterogeneous histologic appearances of this glioblastoma are well demonstrated in specimen B, and varies from very highly cellular regions composed of pleomorphic nuclei, including multinucleated neoplastic cells without significant associated cytoplasm or processes, to well differentiated neoplastic astrocytes with prominent eosinophilic cytoplasm and fibrillary processes. Microvascular proliferation is prominent, as are foci of necrosis and abundant mitoses are present. Immunohistochemistry for GFAP is positive in many of the neoplastic astrocytes. The neurofilament demonstrates the background of axonal processes.

Intraoperative Diagnosis

FS1 (A) Brain, left anterior temporal, biopsy: Malignant glioma; favor glioblastoma multiforme. Tissue section and cytologic prep.

Gross Description

The specimen is received fresh in three parts, each labeled with the patient's name and medical record number.

Part A is additionally labeled "tumor left brain FS," and consists of a single pink-tan, soft tissue fragment measuring 0.4 x 0.4 x 0.2 cm. A portion of the specimen is selected for squash preparation; a portion is selected for frozen section 1 and subsequently placed in cassette A1. The remaining tissue is submitted for

[page 2 of 2]
permanent section in cassette 2.

Part B, labeled "tumor," consists of multiple tan-pink, soft fragments of tissue measuring 4.2 x 3.0 x 1.5 cm in aggregate. The specimen is entirely submitted in cassettes B1-B6.

Part C, labeled "cannister contents," consists of a clear, plastic cannister containing blood-tinged fluid and multiple, irregular fragments of tissue measuring 2.0 x 1.1 x 0.2 cm. The specimen is wrapped in tissue and entirely submitted in cassette C1.

The immunoperoxidase stain(s) reported above were developed and their performance characteristics determined by the . They have not been cleared or approved by the U. S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 ("CLIA") as qualified to perform high-complexity clinical testing.

Clinical History

The patient is a -year-old man with a left anterior temporal ring-enhancing lesion.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

Signed

Source: NCI Genomic Data Commons file 86a01e20-ce90-4982-994f-3ac11331bb60 (TCGA-08-0353.20A53C9E-D401-4990-8C95-E6B53AB5F851.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).